Surgical pathology report (de-identified scan), TCGA case TCGA-AS-3778, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site St. Joseph's Medical Center-(MD), specimen TCGA-AS-3778-01A (Primary Tumor).

[page 1 of 2]
SP TYPE: SURGICAL P OTHR DR:

SURGICAL PROCEDURES:
EXCISION

GROSS DESCRIPTION

The specimen is submitted fresh as "right partial nephrectomy" and consists of a 16 gram, 5 x 3.5 x 3 cm excised partial nephrectomy specimen received with a 5 x 3.2 cm surgical resection margin which is inked black. The capsular surface shows a well circumscribed, firm bulging mass. The capsule is inked blue. Sectioning reveals a 3.1 x 2.5 x 1.7 cm well circumscribed orange to yellow focally cystic, focally hemorrhagic mass which grossly appears to abut the blue inked capsular surface measuring 0.4 cm from the closest black ink surgical resection margin. The remainder of the cut surface consists of tan brown glistening smooth grossly unremarkable parenchyma with a 0.7 cm in thickness cortex and well defined corticomedullary junction. No other discreet masses or nodularities are grossly identified. Representative sections are submitted, 3 (3).

Please note: a portion of the tumor mass is submitted for study collection.

FINAL DIAGNOSIS

KIDNEY, RIGHT, PARTIAL NEPHRECTOMY:

- CLEAR CELL RENAL CELL CARCINOMA. SEE SYNOPTIC REPORT.

SYNOPTIC REPORT

SYNOPTIC REPORT: KIDNEY
(CAP/AJCC/ACS - REQUIRED ELEMENTS)

SPECIMEN TYPE: PARTIAL NEPHRECTOMY

LATERALITY: RIGHT

TUMOR SITE: MID-ANTERIOR

[page 2 of 2]
SYNOPTIC REPORT

(Continued)

TUMOR FOCALITY: UNIFOCA
TUMOR SIZE: 3.1 CM
MACROSCOPIC EXTENT OF TUMOR: LIMITED TO KIDNEY
HISTOLOGIC TYPE: CLEAR CELL
HISTOLOGIC GRADE (FUHRMAN NUCLEAR GRADE): 1 OF 4
VENOUS (INCL. IVC) INVOLVEMENT (IF PRESENT, SPECIFY): ABSENT
ADRENAL INVOLVEMENT: ABSENT

MARGINS:

f,,, CAPSULAR, PARENCHYMAL: TUMOR IS 2 MM FROM THE PARENCHYMAL RESECTION
MARGIN.

f,,, PERINEPHRIC FAT: UNINVOLVED

f,,, RENAL VEIN: N/A

f,,, URETER: N/A

LYMPH NODES:

f,,, # INVOLVED/ # EXAMINED: N/A

OTHER PERTINENT FINDINGS:

- THE ADJACENT BENIGN KIDNEY PARENCHYMA SHOWS NO SIGNIFICANT
ABNORMALITY.

pTNM STAGE: pT1a NX

Source: NCI Genomic Data Commons file e6cd9244-b359-4725-a5ae-7122af8d5d1f (TCGA-AS-3778.B52C44AC-D91A-40C5-978C-F1168D546215.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).